Somatic mutation profile of tumor specimen MMRF_2584_1_BM_CD138pos (aliquot MMRF_2584_1_BM_CD138pos_T1_KHS5U_L13290) from MMRF case MMRF_2584, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.1 years (20,839 days).
Specimen MMRF_2584_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e91a8b04-2214-462b-a5a5-96f2ef322076.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2584_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2584_1_PB_WBC_C2_KHS5U_L13291; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0e2fe1c-293c-453f-be55-648a46a887d9

The open-access MAF lists 57 somatic variants for this specimen: 30 protein-altering or splice-affecting, 4 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, 3'UTR 17, Silent 4, Intron 3, Frame Shift Del 1, 3'Flank 1, RNA 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALAD | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.204); catalogued as COSV52958792; called by muse, mutect2, varscan2
- C9 | c.358A>T p.N120Y | Missense Mutation (SNP) | VAF 76/185 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54674020; called by muse, mutect2, varscan2
- CAVIN1 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.704); catalogued as COSV63811370; called by muse, mutect2
- CFH | c.3029C>T p.A1010V | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs1464197680, CM1512052, COSV100809898; called by muse, mutect2, varscan2
- IGHJ6 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 14/53 reads (26%) | PolyPhen probably damaging (0.998); catalogued as rs542162651; called by muse, varscan2
- IGHV1-24 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 107/113 reads (95%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs781997774; called by muse, mutect2, varscan2
- IGHV3-23 | c.39T>G p.I13M | Missense Mutation (SNP) | VAF 52/58 reads (90%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.131); catalogued as rs782246947; called by muse, varscan2
- LRP2 | c.10652G>A p.R3551H | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs545303364, COSV55548085; called by muse, mutect2, varscan2
- MMRN2 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 68/274 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs771512296, COSV64401445; called by muse, mutect2, varscan2
- MORC1 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 82/156 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV51730439; called by muse, mutect2, varscan2
- OXGR1 | c.275A>G p.Y92C | Missense Mutation (SNP) | VAF 117/239 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1389044854; called by muse, mutect2, varscan2
- PSMD1 | c.2659G>A p.A887T | Missense Mutation (SNP) | VAF 69/169 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.173); catalogued as rs1376612679; called by muse, mutect2, varscan2
- STAT3 | c.1022C>G p.T341S | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as CD086675, CM136354; called by muse, mutect2, varscan2
- TBX21 | c.1396C>T p.R466W | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.333); catalogued as rs752147705, COSV51596494; called by muse, mutect2, varscan2
- TSHZ2 | c.2480G>A p.R827H | Missense Mutation (SNP) | VAF 91/180 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.877); catalogued as rs112191590; called by muse, mutect2, varscan2
- ATRX | c.3841A>C p.K1281Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CAND1 | c.1388A>G p.N463S | Missense Mutation (SNP) | VAF 72/172 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CXCL14 | c.211A>G p.T71A (on ENST00000337225; = p.T59A on NM_004887.5) | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DSCAML1 | c.2056A>C p.I686L (on ENST00000321322; = p.I626L on NM_020693.4) | Missense Mutation (SNP) | VAF 100/193 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- HTN3 | c.25A>C p.I9L | Missense Mutation (SNP) | VAF 137/334 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- IL18BP | c.278C>A p.P93H | Missense Mutation (SNP) | VAF 80/199 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- LY6D | c.324C>G p.H108Q | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PCLO | c.14028G>T p.K4676N | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLK4 | c.1057A>G p.S353G | Missense Mutation (SNP) | VAF 134/306 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRR36 | c.2750C>A p.A917D | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.16); called by muse, mutect2, varscan2
- RMND1 | c.302_306del p.F101Yfs*15 | Frame Shift Del (DEL) | VAF 74/175 reads (42%) | called by mutect2, pindel, varscan2
- SCCPDH | c.1248A>T p.K416N | Missense Mutation (SNP) | VAF 21/257 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2
- SLITRK3 | c.2492T>G p.V831G | Missense Mutation (SNP) | VAF 140/250 reads (56%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TCP11X2 | c.1300A>T p.K434* | Nonsense Mutation (SNP) | VAF 12/109 reads (11%) | called by muse, mutect2, varscan2
- TLR2 | c.299G>A p.G100D | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- C9orf78 | c.732G>A p.K244= | Silent (SNP) | VAF 66/237 reads (28%) | called by muse, mutect2
- GPI | c.1419A>C p.P473= | Silent (SNP) | VAF 88/179 reads (49%) | called by muse, mutect2, varscan2
- IGLV10-54 | c.285T>A p.I95= | Silent (SNP) | VAF 64/134 reads (48%) | catalogued as rs1406682167; called by muse, varscan2
- PCDHB8 | c.2328G>A p.Q776= | Silent (SNP) | VAF 41/103 reads (40%) | catalogued as COSV99176359; called by muse, mutect2, varscan2
- ADAM23 | c.*1962T>A | 3'UTR (SNP) | VAF 22/128 reads (17%) | called by muse, mutect2, varscan2
- ATAD1 | c.*2621T>C | 3'UTR (SNP) | VAF 25/69 reads (36%) | called by muse, mutect2, varscan2
- CPT1A | c.*587A>T | 3'UTR (SNP) | VAF 23/45 reads (51%) | called by muse, mutect2, varscan2
- GASK1B | c.*1519C>T | 3'UTR (SNP) | VAF 31/65 reads (48%) | called by muse, mutect2, varscan2
- GRB10 | c.*2C>T | 3'UTR (SNP) | VAF 90/168 reads (54%) | catalogued as rs919918053; called by muse, mutect2, varscan2
- GTPBP4 | c.*2193T>C | 3'UTR (SNP) | VAF 3/45 reads (7%) | catalogued as COSV99479365; called by muse, mutect2
- HERC3 | c.1069+462C>G | Intron (SNP) | VAF 20/38 reads (53%) | called by muse, mutect2, varscan2
- HTR2C | c.*702T>G | 3'UTR (SNP) | VAF 28/34 reads (82%) | called by muse, mutect2, varscan2
- IRX1 | c.*291C>T | 3'UTR (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2, varscan2
- MCMDC2 | chr8:66922428 T>C | 3'Flank (SNP) | VAF 8/20 reads (40%) | catalogued as rs763368201; called by muse, varscan2
- MIR4477B | n.39C>T | RNA (SNP) | VAF 5/63 reads (8%) | catalogued as rs751191207; called by muse, mutect2
- MMP11 | chr22:23768539 G>T | 5'Flank (SNP) | VAF 7/30 reads (23%) | catalogued as rs878942517; called by muse, varscan2
- NCAPH | c.*367C>T | 3'UTR (SNP) | VAF 26/42 reads (62%) | called by muse, mutect2, varscan2
- NPAP1 | c.*2276G>A | 3'UTR (SNP) | VAF 25/59 reads (42%) | catalogued as COSV61511140; called by muse, mutect2, varscan2
- NTRK3 | c.*16123T>A | 3'UTR (SNP) | VAF 54/120 reads (45%) | called by muse, mutect2, varscan2
- ODR4 | c.*655T>A | 3'UTR (SNP) | VAF 14/26 reads (54%) | catalogued as rs1340872070, COSV55217454; called by mutect2, varscan2
- PPP1R13B | c.*1021C>T | 3'UTR (SNP) | VAF 53/97 reads (55%) | called by muse, mutect2, varscan2
- RASGRF2 | c.*523G>A | 3'UTR (SNP) | VAF 29/71 reads (41%) | called by muse, mutect2, varscan2
- ST6GALNAC3 | c.*5484A>G | 3'UTR (SNP) | VAF 23/66 reads (35%) | catalogued as rs984070582; called by muse, mutect2, varscan2
- TRAF2 | c.-29+192G>A | Intron (SNP) | VAF 26/49 reads (53%) | called by muse, mutect2, varscan2
- TRAF2 | c.-29+193A>T | Intron (SNP) | VAF 26/50 reads (52%) | called by muse, mutect2, varscan2
- TUBE1 | c.*649T>A | 3'UTR (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
- ZNF777 | c.*105C>A | 3'UTR (SNP) | VAF 30/57 reads (53%) | catalogued as COSV99925173; called by muse, mutect2, varscan2
